Somatic mutation profile of tumor specimen ASCProject_0007_T1_WES (aliquot ASCProject_0007_T1_WES_1) from CMI case ASCProject_0007, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: male; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 41.9 years (15,314 days).
Specimen ASCProject_0007_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Bladder; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bb4dfa4-b0f7-42ad-b884-72c43b9c2a0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0007_SALIVA (Saliva), aliquot ASCProject_0007_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8618a65d-900b-443a-a283-e39cc903e24e

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 4, 5'Flank 2, Frame Shift Del 1, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 20/272 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs483352695, CM942294, COSV52664850, COSV52707693, COSV52949209, COSV53107767; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACSF2 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as rs1331854655; called by muse, mutect2
- CACNA1E | c.5360A>G p.Y1787C | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV62415889; called by muse, mutect2
- CLIC6 | c.1453G>A p.G485R (on ENST00000360731 / NM_001317009.2; = p.G467R on NM_053277.3) | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868729882, COSV62449513; called by muse, mutect2, varscan2
- CSMD3 | c.7802G>A p.R2601Q (on ENST00000297405 / NM_001363185.1; = p.R2497Q on NM_052900.3) | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs564995042, COSV52100352, COSV52124954; called by muse, mutect2, varscan2
- ELAVL4 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs763451875; called by muse, mutect2, varscan2
- EPHA5 | c.332A>C p.N111T | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56655156; called by muse, mutect2, varscan2
- KRT33A | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as rs755502314, COSV50380088; called by muse, mutect2
- MACF1 | c.16256A>G p.D5419G (on ENST00000372915; = p.D3352G on NM_012090.5) | Missense Mutation (SNP) | VAF 21/263 reads (8%) | catalogued as COSV57122714; called by muse, mutect2
- PCDHGA5 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.358); catalogued as COSV54040478; called by muse, mutect2
- RLF | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs865775117; called by muse, mutect2
- SLC33A1 | c.1414G>C p.D472H | Missense Mutation (SNP) | VAF 44/313 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762449972; called by muse, mutect2, varscan2
- SLC6A2 | c.924G>T p.W308C | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54918653; called by muse, mutect2
- THSD7B | c.4343C>T p.T1448I (on ENST00000272643; = p.T1446I on NM_001316349.2) | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1188034399, COSV55679100; called by muse, mutect2
- TLN2 | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as COSV100168271; called by muse, mutect2
- USP45 | c.550T>C p.C184R | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.018); catalogued as rs1408754609; called by muse, mutect2
- AC004922.1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- C11orf95 | c.770A>C p.E257A | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2
- GJB3 | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- GPR50 | c.1678C>G p.L560V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); called by muse, varscan2
- GUCY2C | c.2080A>G p.R694G | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- KCNC3 | c.1895G>C p.G632A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIDEAS | c.469_470dup p.Y158Lfs*9 | Frame Shift Ins (INS) | VAF 15/119 reads (13%) | called by mutect2, pindel, varscan2
- PCDH15 | c.3088G>T p.G1030C | Missense Mutation (SNP) | VAF 24/389 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2
- PGK2 | c.661A>T p.I221F | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXND1 | c.714del p.I238Mfs*43 | Frame Shift Del (DEL) | VAF 30/235 reads (13%) | called by mutect2, pindel, varscan2
- RTL3 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TEX45 | c.1179G>T p.Q393H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- HMCN1 | c.4803A>G p.Q1601= | Silent (SNP) | VAF 26/312 reads (8%) | called by muse, mutect2
- PIGC | c.94C>A p.R32= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as rs762595686; called by muse, mutect2
- PKD1L1 | c.582C>T p.V194= | Silent (SNP) | VAF 58/390 reads (15%) | catalogued as rs766566008; called by muse, mutect2, varscan2
- XKR7 | c.867C>T p.D289= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1303010032, COSV73813317; called by muse, mutect2, varscan2
- FAM174B | c.*158T>C | 3'UTR (SNP) | VAF 52/440 reads (12%) | called by muse, mutect2, varscan2
- MFRP | chr11:119343883 C>T | 5'Flank (SNP) | VAF 54/428 reads (13%) | catalogued as rs563717527; called by muse, mutect2, varscan2
- OR4K17 | c.-11G>A | 5'UTR (SNP) | VAF 30/189 reads (16%) | catalogued as COSV59648063; called by muse, mutect2, varscan2
- PHKB | c.2427+978G>A | Intron (SNP) | VAF 26/365 reads (7%) | catalogued as rs1555497423, COSV54525795; called by muse, mutect2
- RNA5-8SP2 | chr16:34158829 G>A | 5'Flank (SNP) | VAF 15/60 reads (25%) | catalogued as rs779355329; called by muse, mutect2, varscan2
- ZNF880 | chr19:52390329 C>A | 3'Flank (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
